Somatic mutation profile of tumor specimen 0DX4FW from CCDI case PBCRAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical meningioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.2 years (6,647 days).
Specimen 0DX4FW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 615d33fd-b235-4c74-a793-ef609282d732.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4EW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1fd177-143e-40b9-80bf-015f65e1b51c

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFRD1 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 14/476 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1468131448; called by muse, mutect2
- RALGAPA2 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 60/398 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs773922641; called by muse, mutect2, varscan2
- ACSL1 | c.1062C>T p.D354= | Silent (SNP) | VAF 12/349 reads (3%) | called by muse, mutect2
- EDF1 | c.318C>T p.I106= | Silent (SNP) | VAF 51/358 reads (14%) | catalogued as rs142743557, COSV56375543; called by muse, mutect2, varscan2
- NEDD1 | c.1230C>T p.F410= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs747798181; called by muse, mutect2, varscan2
- SPDEF | c.9C>T p.S3= | Silent (SNP) | VAF 21/308 reads (7%) | catalogued as rs1020397262, COSV65001219; called by muse, mutect2
- ZBTB11 | c.2628C>T p.H876= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV57244014; called by muse, mutect2
- TM4SF5 | c.*41C>T | 3'UTR (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
